Gene-level copy-number profile of tumor specimen REBC-ACA3-TTP1-A from REBC case REBC-ACA3, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-ACA3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e2b64a28-bee8-43f7-b6e6-4b8d2ae28ef1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ACA3-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/2dfd3882-5548-4c3e-86d8-c7c5a39be502

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 5,333; copy number 2: 52,520; copy number 3: 428; copy number 4: 101.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,704,088–153,726,353, 3 genes: RN7SL372P, GEMIN2P1, Y_RNA.
- chr6:60,281,444–60,546,660, 1 gene: AC244258.1.
- chr9:40,767,870–40,883,763, 2 genes: AL353626.1, AL353626.2.
- chr14:18,333,726–18,343,144, 2 genes: CR383658.1, RNU6-458P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,273. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
